Somatic mutation profile of tumor specimen TCGA-G2-A3IE-01A (aliquot TCGA-G2-A3IE-01A-11D-A20D-08) from TCGA case TCGA-G2-A3IE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 52.0 years (18,983 days).
Specimen TCGA-G2-A3IE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fd80f07-64b0-4587-8393-0fd4f4f49326.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-A3IE-10A (Blood Derived Normal), aliquot TCGA-G2-A3IE-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/290a9161-de4e-40be-90aa-ae5c43aab7c0

The open-access MAF lists 404 somatic variants for this specimen: 296 protein-altering or splice-affecting, 96 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 250, Silent 96, Nonsense Mutation 26, Splice Site 7, Frame Shift Del 6, Intron 5, RNA 4, In Frame Del 3, Nonstop Mutation 2, 5'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.2742G>T p.Q914H | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV55950904; called by muse, mutect2, varscan2
- ABCB1 | c.2041A>G p.K681E | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV55950914; called by muse, mutect2
- ABCB1 | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55946476, COSV55950927; called by muse, mutect2, varscan2
- ADGRV1 | c.16474G>A p.D5492N | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV67984952; called by muse, mutect2, varscan2
- ADGRV1 | c.16567G>T p.D5523Y | Missense Mutation (SNP) | VAF 89/159 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV67984955; called by muse, mutect2, varscan2
- AFF1 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 87/425 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.103); catalogued as COSV57116338, COSV57119701, COSV57122358; called by muse, mutect2, varscan2
- AFF1 | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); catalogued as COSV57119707; called by muse, mutect2, varscan2
- AK7 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV50869271, COSV50871563; called by muse, mutect2, varscan2
- AKAP13 | c.7984G>C p.E2662Q (on ENST00000394518 / NM_007200.5; = p.E2666Q on NM_006738.6) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV63456762; called by muse, mutect2, varscan2
- ALDH1A2 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV51080145; called by muse, mutect2, varscan2
- ALDH3B1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs200367510, COSV50290376; called by muse, mutect2, varscan2
- ALPK2 | c.3901G>C p.E1301Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64492950; called by muse, mutect2, varscan2
- ANKRD42 | c.817C>G p.P273A | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV52615789; called by muse, mutect2, varscan2
- ARHGAP12 | c.2402A>G p.Y801C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs748984702, COSV60963185; called by muse, mutect2, varscan2
- ARHGAP32 | c.6032G>T p.G2011V (on ENST00000310343 / NM_001378025.1; = p.G1662V on NM_014715.4) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV59847535; called by muse, mutect2, varscan2
- ARHGEF1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as COSV61527686; called by muse, mutect2, varscan2
- ARRDC3 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as COSV54365132; called by muse, mutect2, varscan2
- ASNSD1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1467744718, COSV53623700; called by muse, mutect2, varscan2
- ATAD5 | c.3320C>T p.S1107L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs552886395, COSV58974514; called by muse, mutect2, varscan2
- ATP13A3 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.111); catalogued as COSV55462743; called by muse, mutect2, varscan2
- ATRX | c.6413C>T p.S2138F | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64876377; called by muse, mutect2, varscan2
- AUP1 | c.984G>C p.L328F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs770057558, COSV57816962, COSV57817188; called by muse, mutect2, varscan2
- BBS9 | c.1780A>C p.K594Q (on ENST00000242067 / NM_001348036.1; = p.K554Q on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV54167388; called by muse, mutect2, varscan2
- BICRAL | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV58405379; called by muse, mutect2, varscan2
- BTAF1 | c.4850C>T p.S1617L | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56429799, COSV56433860; called by muse, mutect2, varscan2
- BTNL8 | c.578T>G p.I193S | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV51458644; called by muse, mutect2, varscan2
- C8orf37 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 102/411 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54412487; called by muse, mutect2, varscan2
- CABP2 | c.443C>G p.T148R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53708829; called by muse, varscan2
- CAMTA1 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.006); catalogued as rs772482641, COSV57884321; called by muse, mutect2, varscan2
- CAND2 | c.2845G>A p.E949K (on ENST00000456430 / NM_001162499.2; = p.E856K on NM_012298.3) | Missense Mutation (SNP) | VAF 109/175 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201393756, COSV55989772; called by muse, mutect2, varscan2
- CCBE1 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV71672616; called by muse, mutect2, varscan2
- CCDC151 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV52951356; called by muse, mutect2, varscan2
- CCDC18 | c.2284G>A p.E762K (on ENST00000343253 / NM_001306076.1; = p.E763K on NM_206886.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as COSV58143389; called by muse, mutect2, varscan2
- CCL1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 102/335 reads (30%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.866); catalogued as rs765917777, COSV56774669, COSV56775699; called by muse, mutect2, varscan2
- CDH1 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55727608, COSV55732475, COSV55742678; called by muse, varscan2
- CDH1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV55732488; called by muse, mutect2, varscan2
- CDON | c.2726A>C p.E909A | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV54997768; called by muse, mutect2
- CFAP69 | c.1501G>C p.D501H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60185779; called by muse, mutect2, varscan2
- CIITA | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV60854069; called by muse, mutect2, varscan2
- CLEC4C | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs868220036, COSV63582218, COSV63582649; called by muse, mutect2, varscan2
- CLIP4 | c.1589T>G p.V530G | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60749103; called by muse, mutect2, varscan2
- CNNM2 | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV63995894; called by muse, mutect2, varscan2
- CNNM2 | c.1820C>G p.S607C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63998553; called by muse, mutect2, varscan2
- CNOT10 | c.2103G>C p.Q701H | Missense Mutation (SNP) | VAF 135/503 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100094409, COSV59391980; called by muse, mutect2, varscan2
- COL27A1 | c.4681C>T p.R1561W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780973056, COSV61925935; called by muse, varscan2
- CPLANE1 | c.9185G>T p.G3062V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.191); catalogued as COSV57059653; called by muse, mutect2, varscan2
- CTNNA1 | c.2563C>G p.P855A | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV57073705; called by muse, mutect2
- CXADR | c.831C>T p.I277= | Splice Region (SNP) | VAF 21/51 reads (41%) | catalogued as COSV53028980; called by muse, mutect2, varscan2
- CYP1A2 | c.727C>G p.R243G | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59659687; called by muse, mutect2, varscan2
- DIS3L | c.2735C>T p.S912L (on ENST00000319212 / NM_001143688.3; = p.S829L on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as rs751055308, COSV56019996; called by muse, mutect2, varscan2
- DLEC1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57299582; called by muse, mutect2
- DLG5 | c.1811C>G p.S604C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64947950; called by muse, mutect2, varscan2
- DNAH1 | c.7963G>A p.E2655K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70228926; called by muse, mutect2, varscan2
- DNAH2 | c.1189C>T p.H397Y | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.824); catalogued as COSV50014492; called by muse, mutect2, varscan2
- DNAJC13 | c.3975C>G p.F1325L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV53450444; called by muse, mutect2, varscan2
- DPYD | c.1562T>A p.L521Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64593373, COSV64597364; called by muse, mutect2, varscan2
- E2F8 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51463358; called by muse, mutect2, varscan2
- EHHADH | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV51630068; called by muse, mutect2, varscan2
- ERG | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV55731962; called by muse, mutect2, varscan2
- ETFBKMT | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV55671350; called by muse, mutect2, varscan2
- F13A1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs139164988, COSV99342214; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCI | c.1976C>G p.S659C | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.698); catalogued as rs776139524, COSV100167723, COSV55526849; called by muse, mutect2, varscan2
- FANCI | c.3641C>G p.S1214C (on ENST00000310775 / NM_001376911.1; = p.S1154C on NM_018193.3) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV55526873; called by muse, mutect2, varscan2
- FARP1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV60337094; called by muse, mutect2, varscan2
- FBXW4 | c.1467G>T p.E489D | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV100489628, COSV58707862; called by muse, mutect2
- FGF17 | c.91C>G p.P31A | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.853); catalogued as COSV63925521; called by muse, mutect2, varscan2
- FIGNL1 | c.1903C>G p.Q635E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.113); catalogued as COSV63553490; called by muse, mutect2, varscan2
- FKBP15 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53034607; called by muse, varscan2
- FNBP1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV63087319; called by muse, mutect2, varscan2
- FNBP4 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV55448523; called by muse, mutect2, varscan2
- FOLR3 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as rs752978331, COSV61530160; called by muse, mutect2, varscan2
- FOSL1 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV57027962; called by muse, mutect2, varscan2
- GALNT17 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1374937221, COSV61149949, COSV61154773; called by muse, mutect2
- GDA | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.085); catalogued as COSV52993022; called by muse, mutect2, varscan2
- GLRB | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.535); catalogued as COSV52416758; called by muse, mutect2, varscan2
- GRAMD1B | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV59203998; called by muse, mutect2, varscan2
- GRIN2A | c.3341G>C p.R1114T | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as rs1555482504, COSV58022882, COSV58027558; called by muse, mutect2, varscan2
- GRIN2A | c.2075G>C p.R692T | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58024115, COSV58032126; called by muse, mutect2, varscan2
- HEG1 | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1401803502, COSV60761882; called by muse, mutect2, varscan2
- HERC1 | c.12982A>G p.T4328A | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs774606926, COSV71247770; called by muse, mutect2, varscan2
- HIPK4 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV52520945; called by muse, mutect2, varscan2
- HNRNPDL | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 81/159 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.073); catalogued as COSV55022598, COSV55022678; called by muse, mutect2, varscan2
- HNRNPF | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61560997; called by muse, mutect2, varscan2
- HSPA12A | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100979811; called by muse, mutect2
- IGHV1-18 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 30/613 reads (5%) | catalogued as rs375042034; called by muse, mutect2
- IGSF5 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as rs748941524, COSV66029335; called by muse, mutect2, varscan2
- IGSF9B | c.187T>A p.F63I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as COSV58067419; called by muse, mutect2, varscan2
- IKBKB | c.1243C>G p.Q415E | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV100645711, COSV60597290; called by muse, mutect2, varscan2
- IL10RB | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 24/106 reads (23%) | catalogued as COSV51615484, COSV99270119; called by muse, mutect2
- IL17RE | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.458); catalogued as COSV55968199; called by muse, varscan2
- IL21R | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV61970274; called by muse, mutect2, varscan2
- ITPKB | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs564970025, COSV55261590; called by muse, mutect2, varscan2
- ITSN1 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as COSV66082968; called by muse, mutect2, varscan2
- JPH3 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227305136, COSV52467570; called by muse, mutect2, varscan2
- KBTBD3 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV73241405; called by muse, mutect2, varscan2
- KCNF1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.122); catalogued as rs1182064793, COSV54463399; called by muse, mutect2, varscan2
- KCNH4 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52917340; called by muse, varscan2
- KDM1A | c.539A>G p.Q180R | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV63087997; called by muse, mutect2, varscan2
- KDM7A | c.1673A>G p.N558S | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); catalogued as rs763271453, COSV50091419; called by muse, mutect2, varscan2
- KEAP1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV50280201, COSV50642330; called by muse, mutect2, varscan2
- KIN | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 91/240 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59621617; called by muse, mutect2, varscan2
- KLHL23 | c.1367-1G>C p.X456_splice | Splice Site (SNP) | VAF 10/17 reads (59%) | catalogued as COSV55867134; called by mutect2, varscan2
- KMT2C | c.12035G>C p.G4012A | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51438123; called by muse, mutect2, varscan2
- LAMC3 | c.3420G>C p.E1140D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV63089671, COSV63091115; called by muse, mutect2, varscan2
- LILRB5 | c.1140C>G p.F380L | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60257340; called by muse, mutect2, varscan2
- LINS1 | c.2169C>G p.I723M | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1160809037, COSV59078874; called by muse, mutect2, varscan2
- LMBR1L | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as COSV57267625; called by muse, mutect2, varscan2
- LMLN | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV57600760, COSV57604860; called by muse, mutect2, varscan2
- LRFN2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV57827271; called by muse, mutect2, varscan2
- LRP4 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66135776; called by muse, mutect2
- LRRC37B | c.775C>G p.Q259E | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.93); catalogued as COSV58952445; called by muse, mutect2, varscan2
- MAP1A | c.5881G>A p.D1961N | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); catalogued as rs373186264, COSV104393434; called by muse, mutect2, varscan2
- MAP1A | c.6427G>T p.E2143* | Nonsense Mutation (SNP) | VAF 24/131 reads (18%) | catalogued as COSV55814644; called by muse, mutect2, varscan2
- MAP1A | c.7603G>A p.E2535K | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55808628; called by muse, mutect2, varscan2
- MAP3K10 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.101); catalogued as COSV53422246; called by muse, mutect2, varscan2
- MAPK3 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV53773407; called by muse, mutect2, varscan2
- MGRN1 | c.773A>T p.N258I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52150914; called by muse, mutect2, varscan2
- MIA3 | c.5086C>T p.R1696* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as rs1040322499; called by muse, mutect2, varscan2
- MN1 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV56558292; called by muse, mutect2, varscan2
- MOCS3 | c.956C>A p.S319* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as COSV54866130, COSV54866265; called by muse, mutect2, varscan2
- MORF4L1 | c.580G>A p.E194K (on ENST00000331268 / NM_206839.2; = p.E155K on NM_006791.4) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV58704471; called by muse, mutect2, varscan2
- MPRIP | c.2967G>A p.M989I | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV57927067; called by muse, mutect2, varscan2
- MRM1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs1446047239; called by muse, mutect2, varscan2
- MRPL19 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62567021; called by muse, mutect2, varscan2
- MRPS30 | c.326T>A p.F109Y | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV72361321; called by muse, mutect2, varscan2
- MSH5 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 120/212 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs142533600; called by muse, mutect2, varscan2
- MTERF3 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.172); catalogued as COSV54632704; called by muse, mutect2, varscan2
- MUC17 | c.4127C>T p.S1376L | Missense Mutation (SNP) | VAF 152/498 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV60288236; called by muse, mutect2, varscan2
- MUC20 | c.437A>C p.D146A | Missense Mutation (SNP) | VAF 57/501 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV57849627; called by muse, mutect2, varscan2
- MUC3A | c.8759C>T p.S2920L | Missense Mutation (SNP) | VAF 86/465 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as COSV60215592; called by muse, mutect2, varscan2
- MYCBPAP | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.465); catalogued as COSV60407744; called by muse, mutect2, varscan2
- MYH10 | c.2295G>C p.Q765H | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV52600846; called by muse, mutect2, varscan2
- MYH3 | c.2502C>A p.F834L | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV56864802; called by muse, mutect2, varscan2
- MYLK | c.3300C>G p.F1100L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV60610068; called by muse, mutect2, varscan2
- NAV3 | c.3785C>G p.S1262C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV57059358, COSV57076543; called by muse, mutect2, varscan2
- NBEAL1 | c.5399A>T p.K1800M | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV71374316; called by muse, mutect2, varscan2
- NEB | c.17238G>C p.K5746N | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs544200886, COSV51383305; called by muse, mutect2, varscan2
- NEK4 | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51780259; called by muse, mutect2, varscan2
- NFATC1 | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV53700095; called by muse, mutect2, varscan2
- NID1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 34/90 reads (38%) | catalogued as COSV51628194; called by muse, mutect2, varscan2
- NMD3 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63618529; called by muse, mutect2, varscan2
- NR1H2 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as rs745914829; called by muse, mutect2, varscan2
- NRG1 | c.1585C>A p.Q529K (on ENST00000405005 / NM_013964.5; = p.Q534K on NM_013956.5) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55158950, COSV99829559; called by muse, mutect2, varscan2
- OAS3 | c.1633C>G p.L545V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV57445629; called by muse, mutect2, varscan2
- OR10H1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.337); catalogued as rs1169187924, COSV58473385; called by muse, varscan2
- OR10X1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63767335; called by muse, mutect2
- OR2B6 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV55128875; called by muse, mutect2, varscan2
- OR2B6 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs200986280, COSV55128883; called by muse, mutect2, varscan2
- OR2B6 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV55128889; called by muse, mutect2, varscan2
- OR2T6 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV63216226; called by muse, mutect2, varscan2
- OR4C3 | c.68G>C p.R23T | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV60585786; called by muse, mutect2, varscan2
- OR5M11 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs376747453; called by muse, mutect2, varscan2
- OSBP2 | c.2262G>T p.M754I | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.51); PolyPhen benign (0.163); catalogued as COSV100213165; called by muse, mutect2, varscan2
- OTOGL | c.6883G>C p.G2295R (on ENST00000547103; = p.G2286R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54016640, COSV54020198; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2213G>A p.R738K (on ENST00000259318 / NM_001136562.3; = p.R969K on NM_007203.5) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.695); catalogued as COSV52176112; called by muse, mutect2, varscan2
- PALMD | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as COSV54163740; called by muse, mutect2
- PARP2 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV51639040; called by muse, mutect2, varscan2
- PDHX | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57165957; called by muse, varscan2
- PHF8 | c.304C>T p.R102C (on ENST00000357988 / NM_001184896.1; = p.R66C on NM_015107.3) | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs782556188, COSV57680567; called by muse, mutect2, varscan2
- PIBF1 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58322904; called by muse, mutect2, varscan2
- PIP4K2A | c.854G>C p.R285T | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV60540870; called by muse, mutect2, varscan2
- PIWIL3 | c.918G>C p.Q306H | Missense Mutation (SNP) | VAF 66/440 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs765539196, COSV59995370; called by muse, mutect2, varscan2
- PLCG1 | c.3457G>A p.E1153K | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.405); catalogued as COSV54818493; called by muse, mutect2, varscan2
- PLEKHG2 | c.1244C>G p.P415R | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52682654, COSV52688826; called by muse, mutect2, varscan2
- PLXNB2 | c.1482-1G>T p.X494_splice | Splice Site (SNP) | VAF 10/18 reads (56%) | catalogued as COSV63781651; called by muse, mutect2, varscan2
- PNMA2 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1014437046, COSV72908513; called by muse, mutect2, varscan2
- POFUT1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV65337495; called by muse, mutect2, varscan2
- POLE2 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs944761368, COSV53559726; called by muse, mutect2
- POLR3C | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.316); catalogued as COSV61936531; called by muse, mutect2, varscan2
- PPFIA2 | c.2117C>A p.A706D | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.29); catalogued as COSV61031849; called by muse, mutect2, varscan2
- PRKCZ | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66067425; called by muse, mutect2, varscan2
- PRTG | c.3391C>A p.H1131N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.023); catalogued as COSV66837941; called by muse, mutect2, varscan2
- PRUNE2 | c.2993C>G p.S998* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV65042265; called by muse, mutect2, varscan2
- PSMF1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55673951; called by muse, mutect2, varscan2
- PTPRG | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as COSV55640934; called by muse, mutect2, varscan2
- PTPRT | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61978934; called by muse, mutect2, varscan2
- RALGAPA1 | c.3869G>T p.R1290L | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV51882545; called by muse, mutect2, varscan2
- RELN | c.7916G>A p.R2639H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs369735904; called by muse, mutect2, varscan2
- RIMS4 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 112/358 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as rs935477908, COSV65719704; called by muse, varscan2
- RIT2 | c.520T>A p.F174I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58665229; called by muse, mutect2, varscan2
- RNF40 | c.2157G>C p.K719N | Missense Mutation (SNP) | VAF 146/220 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61214795; called by muse, mutect2, varscan2
- ROBO1 | c.4885G>C p.E1629Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV101458505, COSV71394211; called by muse, mutect2, varscan2
- RPAIN | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774430216, COSV104387489, COSV56705189; called by muse, mutect2, varscan2
- RPTN | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1470182851, COSV60167237; called by muse, mutect2
- RSPH4A | c.1636C>T p.H546Y | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57634607; called by muse, mutect2, varscan2
- SCAF1 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as COSV62183297; called by muse, mutect2, varscan2
- SCAF4 | c.778-1G>A p.X260_splice | Splice Site (SNP) | VAF 28/89 reads (31%) | catalogued as COSV54587100; called by muse, mutect2, varscan2
- SCRIB | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs782093618, COSV57586736; called by muse, mutect2, varscan2
- SCUBE3 | c.2558C>A p.S853Y | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV51456792; called by muse, mutect2, varscan2
- SEC14L1 | c.906G>C p.L302F | Missense Mutation (SNP) | VAF 69/110 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66722216; called by muse, mutect2, varscan2
- SEC24A | c.2621C>G p.S874C | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV67305368; called by muse, mutect2, varscan2
- SEMA6D | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs1485093912, COSV60377265; called by muse, mutect2
- SEPTIN11 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV53582259; called by muse, mutect2, varscan2
- SHROOM1 | c.1047G>C p.Q349H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV60581282; called by muse, mutect2, varscan2
- SLC12A5 | c.2881C>G p.R961G (on ENST00000454036 / NM_001134771.2; = p.R938G on NM_020708.5) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV51644309; called by muse, mutect2, varscan2
- SLC13A1 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52011113; called by muse, mutect2, varscan2
- SLC28A3 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as rs1265842851; called by muse, mutect2, varscan2
- SLC49A3 | c.1648C>T p.H550Y (on ENST00000404286 / NM_001294341.2; = p.H549Y on NM_032219.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs371278586, COSV59140250, COSV59141261; called by muse, mutect2
- SLCO1C1 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1352659537, COSV56872433; called by muse, mutect2, varscan2
- SLCO4A1 | c.1755C>A p.F585L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV53890185, COSV53890788; called by muse, mutect2, varscan2
- SMARCA2 | c.3366C>G p.F1122L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61807232; called by muse, mutect2, varscan2
- SMARCE1 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52861013; called by muse, mutect2, varscan2
- SMC6 | c.2532G>C p.E844D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV61174191; called by muse, mutect2, varscan2
- SOS2 | c.3929A>G p.Y1310C | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53567551; called by muse, mutect2, varscan2
- SPESP1 | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52988713; called by muse, mutect2, varscan2
- STAT1 | c.1874-1G>C p.X625_splice | Splice Site (SNP) | VAF 26/81 reads (32%) | catalogued as COSV63116046; called by muse, mutect2, varscan2
- SV2A | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 120/221 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782021944, COSV64964743; called by muse, mutect2, varscan2
- SYCP2L | c.10-1G>C p.X4_splice | Splice Site (SNP) | VAF 7/80 reads (9%) | catalogued as COSV51653068; called by muse, mutect2
- SYCP2L | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV51653076; called by muse, mutect2, varscan2
- SYNGAP1 | c.232C>G p.R78G | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV53381338, COSV99538149; called by muse, mutect2, varscan2
- SYNGAP1 | c.1951G>T p.E651* | Nonsense Mutation (SNP) | VAF 59/98 reads (60%) | catalogued as rs1554121812, COSV53380814; called by muse, mutect2, varscan2
- SYNPR | c.213G>C p.L71F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55725489; called by muse, mutect2, varscan2
- SYS1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV54781757; called by muse, mutect2, varscan2
- SYT14 | c.188C>G p.S63* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as COSV55054652; called by muse, mutect2, varscan2
- TAMALIN | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53336585; called by muse, mutect2, varscan2
- TARDBP | c.413A>C p.D138A | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53569857; called by muse, mutect2
- TBX3 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57471488; called by muse, mutect2, varscan2
- TENM1 | c.2839G>C p.E947Q | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64431642; called by muse, mutect2, varscan2
- TGFBRAP1 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs1165146488, COSV51512052; called by muse, mutect2
- THAP3 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs775502432, COSV50010984; called by muse, mutect2, varscan2
- THNSL2 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs367584313; called by muse, mutect2
- TIAM1 | c.1728G>A p.M576I | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV54550422; called by muse, mutect2, varscan2
- TLX3 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51539898; called by muse, mutect2, varscan2
- TM9SF4 | c.1928G>C p.*643Sext*27 | Nonstop Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV54105597; called by muse, mutect2, varscan2
- TMEM200A | c.569del p.G190Efs*5 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as COSV51660646, COSV99759845; called by mutect2, pindel, varscan2
- TMEM38B | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as rs11542697, COSV65966126; called by muse, mutect2, varscan2
- TMX2 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.042); catalogued as rs542858051, COSV53554314; called by muse, mutect2, varscan2
- TNFRSF8 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV55796410; called by muse, mutect2, varscan2
- TNRC6A | c.2472G>C p.E824D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV59364174; called by muse, mutect2, varscan2
- TRIM5 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV59899867; called by muse, mutect2, varscan2
- TRIM69 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV57803791; called by muse, mutect2, varscan2
- TRIM72 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV57251073; called by muse, mutect2, varscan2
- TRIP11 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99970566; called by muse, mutect2, varscan2
- TRPV5 | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.801); catalogued as COSV54685649; called by muse, mutect2, varscan2
- TSBP1 | c.1369G>C p.E457Q (on ENST00000617061; = p.E462Q on NM_006781.5) | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV66658773; called by muse, mutect2
- TSPEAR | c.791-1G>C p.X264_splice | Splice Site (SNP) | VAF 17/36 reads (47%) | catalogued as COSV59961696; called by muse, mutect2, varscan2
- TTC7A | c.1965G>T p.K655N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.255); catalogued as COSV55411005; called by muse, mutect2, varscan2
- TUBG2 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.419); catalogued as rs1244237878, COSV52217554; called by muse, varscan2
- TYR | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV54475220; called by muse, mutect2, varscan2
- UBE2C | c.102-2A>G p.X34_splice | Splice Site (SNP) | VAF 44/206 reads (21%) | catalogued as COSV54754948; called by muse, mutect2, varscan2
- UBR2 | c.3116G>A p.R1039K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.074); catalogued as COSV65750121; called by muse, mutect2, varscan2
- UPF1 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.05); catalogued as COSV53196469; called by muse, mutect2, varscan2
- USF3 | c.1737G>C p.Q579H | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV57072590; called by muse, mutect2
- USP4 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55536989, COSV99649014; called by muse, mutect2, varscan2
- VEGFB | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.447); catalogued as COSV58536592; called by muse, mutect2, varscan2
- WDR83 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.415); catalogued as COSV52952064; called by muse, mutect2, varscan2
- XIRP1 | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV61138448; called by muse, varscan2
- XIRP1 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV61138455; called by muse, varscan2
- XIRP2 | c.5371C>T p.Q1791* (on ENST00000628543; = p.Q1966* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as rs761510859, COSV54695400; called by muse, mutect2, varscan2
- ZBTB7C | c.456G>C p.E152D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.981); catalogued as rs772730774, COSV59691465; called by muse, mutect2
- ZFAND6 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV55711823; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV52852496; called by muse, mutect2
- ZMYM6 | c.3873G>C p.L1291F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV64120903; called by muse, mutect2, varscan2
- ZNF232 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51503381; called by muse, varscan2
- ZNF232 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs1021922055, COSV51503393; called by muse, mutect2, varscan2
- ZNF232 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV51503411; called by muse, mutect2, varscan2
- ZNF282 | c.1773C>G p.N591K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV100021331, COSV50479972; called by muse, mutect2, varscan2
- ZNF394 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV58742781; called by muse, mutect2, varscan2
- ZNF441 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.127); catalogued as COSV63539810; called by muse, mutect2, varscan2
- ZNF473 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV54523117; called by muse, mutect2, varscan2
- ZNF502 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 211/531 reads (40%) | catalogued as rs1299153970; called by muse, mutect2, varscan2
- ZNF532 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV60173022; called by muse, mutect2, varscan2
- ZNF689 | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.896); catalogued as COSV54908530; called by muse, mutect2, varscan2
- ZXDC | c.1373G>C p.C458S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60447026; called by muse, mutect2, varscan2
- A1BG | c.253_254del p.G85* | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- ABCA13 | c.7753G>T p.E2585* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- ASIC4 | c.1161G>C p.E387D (on ENST00000347842 / NM_182847.3; = p.E406D on NM_018674.6) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- BICRA | c.2502C>G p.I834M | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.578); called by muse, mutect2
- CACTIN | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- DAP3 | c.638_641del p.R213Kfs*17 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- DDX58 | c.1351_1354del p.Q451Lfs*24 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel
- FAM120A | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 31/51 reads (61%) | called by muse, mutect2, varscan2
- HECTD1 | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.127); called by muse, mutect2
- ICE1 | c.5856G>C p.E1952D | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IGHG4 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 50/568 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- IL17RC | c.1671_1673del p.L559del (on ENST00000295981 / NM_153461.4; = p.L473del on NM_032732.6 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 44/188 reads (23%) | called by pindel, varscan2
- KANK1 | c.2617_2618del p.I873Qfs*10 | Frame Shift Del (DEL) | VAF 23/85 reads (27%) | called by mutect2, pindel, varscan2
- KRBA2 | c.1448C>G p.S483* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- LTB4R2 | c.947dup p.V317Gfs*36 (on ENST00000528054; = p.V286Gfs*36 on NM_019839.5) | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- LY86 | c.99T>A p.C33* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- MEX3A | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MSH3 | c.659C>A p.S220* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- NIPSNAP3A | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NPTN | c.763_768del p.A255_T256del | In Frame Del (DEL) | VAF 39/122 reads (32%) | called by mutect2, pindel, varscan2
- PDE10A | c.1551_1553del p.K517del | In Frame Del (DEL) | VAF 12/78 reads (15%) | called by pindel, varscan2
- SP140 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- SPTAN1 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- STAC3 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- SYNCRIP | c.351_354del p.K117Nfs*20 | Frame Shift Del (DEL) | VAF 19/122 reads (16%) | called by mutect2, pindel, varscan2
- TADA2A | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 112/330 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- TPD52 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- TPTE | c.1598T>A p.V533E (on ENST00000618007 / NM_199261.4; = p.V515E on NM_199259.4) | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WASHC2C | c.3188G>A p.R1063K (on ENST00000336378; = p.R1042K on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- WASHC2C | c.3652G>A p.E1218K (on ENST00000336378; = p.E1197K on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- ZNF232 | c.1334G>C p.*445Sext*15 | Nonstop Mutation (SNP) | VAF 42/68 reads (62%) | called by muse, varscan2
- ABCC6 | c.933C>T p.F311= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs1220230095, COSV52743749; called by muse, mutect2, varscan2
- ACIN1 | c.2598C>T p.I866= | Silent (SNP) | VAF 68/204 reads (33%) | catalogued as COSV52972948; called by muse, mutect2, varscan2
- ACSM3 | c.379C>T p.L127= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV55501345; called by muse, mutect2, varscan2
- ACTRT2 | c.321G>A p.L107= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs1256859682, COSV65759332; called by muse, mutect2, varscan2
- ADGRG1 | c.1485C>G p.L495= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as COSV65635632; called by muse, varscan2
- ALB | c.864C>T p.I288= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV55738067; called by muse, mutect2, varscan2
- ANKS1A | c.1863C>T p.R621= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as COSV64460598; called by muse, mutect2
- ARFGEF3 | c.15G>A p.L5= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.63G>A p.L21= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV52810946, COSV52818421; called by muse, mutect2, varscan2
- ARHGAP25 | c.93G>A p.Q31= (on ENST00000409202 / NM_001007231.3; = p.Q24= on NM_014882.3) | Silent (SNP) | VAF 219/643 reads (34%) | catalogued as rs868045570, COSV54902218; called by muse, mutect2, varscan2
- ASB14 | c.1314G>A p.R438= | Silent (SNP) | VAF 128/307 reads (42%) | catalogued as COSV67467182; called by muse, mutect2, varscan2
- ASPM | c.5814G>A p.R1938= | Silent (SNP) | VAF 70/267 reads (26%) | catalogued as COSV54129660; called by muse, mutect2, varscan2
- BCDIN3D | c.447C>T p.F149= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV61702433; called by muse, mutect2, varscan2
- CACNA1C | c.5238G>A p.E1746= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV59717042, COSV59741542; called by muse, mutect2, varscan2
- CARD11 | c.870G>A p.G290= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV67798551; called by muse, mutect2, varscan2
- CCDC83 | c.1173C>G p.V391= (on ENST00000342404 / NM_001286159.2; = p.V422= on NM_173556.5) | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV54701716; called by muse, mutect2, varscan2
- CDYL | c.1335C>T p.V445= (on ENST00000328908 / NM_001368125.1; = p.V391= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV59359672; called by muse, mutect2
- CFLAR | c.957G>A p.Q319= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as COSV58580134; called by muse, mutect2, varscan2
- COL24A1 | c.4737C>T p.F1579= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV65306079; called by muse, mutect2, varscan2
- COL28A1 | c.2202G>A p.Q734= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as COSV68082062; called by muse, mutect2, varscan2
- CRB3 | c.243G>A p.R81= | Silent (SNP) | VAF 90/200 reads (45%) | catalogued as COSV57568570; called by muse, varscan2
- CSMD2 | c.10107C>T p.F3369= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV53910446; called by muse, mutect2, varscan2
- CSPP1 | c.1884G>A p.P628= (on ENST00000676605; = p.P587= on NM_024790.6) | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs201940935, COSV51582651; called by muse, mutect2, varscan2
- CYFIP1 | c.6G>T p.A2= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs748234246; called by muse, mutect2, varscan2
- DMTF1 | c.87C>A p.L29= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV58685178; called by muse, mutect2, varscan2
- DNAH10 | c.10578C>T p.F3526= (on ENST00000409039; = p.F3465= on NM_207437.3) | Silent (SNP) | VAF 66/166 reads (40%) | catalogued as COSV68993596; called by muse, mutect2, varscan2
- DPP3 | c.1974C>T p.L658= | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as COSV64756772; called by muse, mutect2, varscan2
- DPYD | c.1149A>G p.E383= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs981786730, COSV64597369; called by muse, mutect2, varscan2
- DRD3 | c.1014C>T p.F338= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs374634853; called by muse, mutect2, varscan2
- DSCAML1 | c.5022G>A p.K1674= (on ENST00000321322; = p.K1614= on NM_020693.4) | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV58390343; called by muse, mutect2, varscan2
- DYNC1LI1 | c.720A>G p.V240= | Silent (SNP) | VAF 40/684 reads (6%) | catalogued as rs1054275960, COSV56127509; called by muse, mutect2
- EIF4G2 | c.2019C>G p.L673= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV100379447, COSV60597026; called by muse, mutect2, varscan2
- FAM161A | c.1548C>A p.P516= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV56766013; called by muse, mutect2, varscan2
- FCGBP | c.9273C>T p.T3091= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs1442363435; called by muse, mutect2
- FOXD4 | c.210C>T p.I70= | Silent (SNP) | VAF 19/214 reads (9%) | catalogued as COSV58700148; called by muse, mutect2, varscan2
- GALC | c.183C>T p.V61= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV54325384; called by muse, mutect2, varscan2
- GATA5 | c.768G>A p.R256= | Silent (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- GHSR | c.429C>T p.F143= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV53839291; called by muse, mutect2, varscan2
- GLG1 | c.3102C>G p.L1034= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV52666916, COSV52675633; called by muse, mutect2, varscan2
- GRM4 | c.720G>A p.Q240= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV65213271; called by muse, mutect2, varscan2
- HYAL1 | c.48C>A p.L16= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV56497542; called by muse, mutect2, varscan2
- IGF1R | c.1923G>C p.L641= | Silent (SNP) | VAF 52/114 reads (46%) | catalogued as rs529006369, COSV51286452; called by muse, mutect2, varscan2
- ILRUN | c.90G>A p.E30= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1192275901, COSV64992657; called by muse, mutect2, varscan2
- JAGN1 | c.551G>A p.*184= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1399369966; called by muse, mutect2
- KALRN | c.7464G>A p.V2488= (on ENST00000360013 / NM_001024660.4; = p.V791= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/182 reads (31%) | catalogued as COSV52256107; called by muse, mutect2, varscan2
- KCNH4 | c.1473C>T p.R491= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs748425974, COSV52917365; called by muse, mutect2, varscan2
- KCTD13 | c.792G>A p.L264= | Silent (SNP) | VAF 95/136 reads (70%) | catalogued as COSV58157307; called by muse, mutect2, varscan2
- KEAP1 | c.948G>A p.V316= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV50282948; called by muse, mutect2, varscan2
- KRT2 | c.102G>C p.R34= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV59010384; called by muse, mutect2, varscan2
- MDM4 | c.294C>G p.L98= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV65797620; called by muse, mutect2, varscan2
- METAP1D | c.327C>G p.L109= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV59930142; called by muse, mutect2, varscan2
- MFSD3 | c.1014C>G p.V338= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV56740970; called by muse, mutect2, varscan2
- MKI67 | c.9558G>A p.Q3186= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV64074271; called by muse, mutect2, varscan2
- MOV10L1 | c.270G>C p.L90= | Silent (SNP) | VAF 36/51 reads (71%) | catalogued as COSV53167155, COSV53171161; called by muse, mutect2, varscan2
- MYCBP2 | c.7359G>A p.Q2453= (on ENST00000357337; = p.Q2491= on NM_015057.5) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV62018539; called by muse, mutect2, varscan2
- MYO19 | c.2367C>T p.L789= (on ENST00000614623 / NM_001163735.1; = p.L589= on NM_025109.5) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs780029048; called by muse, mutect2
- MYO1F | c.876G>A p.G292= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as COSV57794995; called by muse, mutect2, varscan2
- NIPAL3 | c.288C>T p.F96= | Silent (SNP) | VAF 60/177 reads (34%) | catalogued as rs751473547, COSV50230891; called by muse, mutect2, varscan2
- OR52I2 | c.345C>T p.F115= | Silent (SNP) | VAF 68/178 reads (38%) | catalogued as COSV57044321; called by muse, varscan2
- OTOF | c.1389G>A p.Q463= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV55502714; called by muse, mutect2, varscan2
- PDGFD | c.57G>A p.R19= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100157687, COSV56377754; called by muse, mutect2, varscan2
- PEG3 | c.186G>A p.K62= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV55633201; called by muse, mutect2, varscan2
- PFKL | c.1611C>T p.F537= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs373085878; called by muse, mutect2, varscan2
- PRPF31 | c.1461C>T p.L487= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs148353051, COSV58085272; called by muse, mutect2, varscan2
- PTPRT | c.729C>G p.V243= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV61980570; called by muse, mutect2, varscan2
- PYGM | c.2409C>T p.I803= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as COSV51216828; called by muse, mutect2, varscan2
- RARG | c.99C>T p.L33= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100553304; called by muse, mutect2
- REPIN1 | c.462C>T p.F154= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1254748035, COSV68292243; called by muse, mutect2, varscan2
- SARDH | c.2049C>T p.I683= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs748781646, COSV64098659; called by muse, mutect2, varscan2
- SAXO1 | c.1365C>T p.S455= | Silent (SNP) | VAF 58/110 reads (53%) | catalogued as COSV65870043; called by muse, mutect2, varscan2
- SCAMP5 | c.159G>A p.V53= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV62643408; called by muse, mutect2, varscan2
- SCAPER | c.2925T>C p.N975= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs746812156, COSV57740240; called by muse, mutect2, varscan2
- SCUBE3 | c.2160G>C p.R720= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV51456771; called by muse, mutect2, varscan2
- SEPHS1 | c.1113G>C p.R371= | Silent (SNP) | VAF 96/325 reads (30%) | catalogued as COSV59258279; called by muse, mutect2, varscan2
- SH3BP5 | c.1302C>T p.L434= | Silent (SNP) | VAF 202/377 reads (54%) | catalogued as COSV53744051, COSV99507943; called by muse, mutect2, varscan2
- SLC18A3 | c.573C>T p.F191= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV60319364; called by muse, mutect2, varscan2
- SLC22A2 | c.1140C>T p.F380= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV65265718, COSV65266317; called by muse, mutect2, varscan2
- SLCO1B1 | c.1233A>G p.S411= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV57011033; called by muse, mutect2, varscan2
- SMIM7 | c.36G>A p.L12= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV51818951; called by muse, mutect2, varscan2
- SNIP1 | c.984C>T p.I328= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV56166504; called by muse, mutect2, varscan2
- SNX33 | c.1395C>G p.L465= | Silent (SNP) | VAF 87/224 reads (39%) | catalogued as COSV57913459; called by muse, mutect2, varscan2
- SRBD1 | c.2973C>T p.L991= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as rs764591251, COSV55398567; called by muse, mutect2, varscan2
- STAB2 | c.1197G>A p.L399= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV66338766; called by muse, mutect2, varscan2
- SULT1C4 | c.63C>T p.Y21= | Silent (SNP) | VAF 68/226 reads (30%) | catalogued as rs182283560; called by muse, mutect2, varscan2
- TASOR2 | c.6613C>T p.L2205= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs369777988; called by muse, mutect2, varscan2
- TBXAS1 | c.906C>T p.D302= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs186487639; called by muse, mutect2, varscan2
- TEP1 | c.4797C>T p.P1599= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs200043242, COSV52992365, COSV99403008; called by muse, mutect2, varscan2
- TFAP4 | c.705G>A p.V235= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52597577; called by muse, mutect2, varscan2
- TMEM94 | c.1608G>C p.G536= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV58595522; called by muse, mutect2, varscan2
- VASH1 | c.765G>A p.K255= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1346353343, COSV51336031; called by muse, mutect2, varscan2
- XPO5 | c.3459C>G p.L1153= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV54829900; called by muse, mutect2, varscan2
- ZNF251 | c.213G>A p.K71= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV52957331; called by muse, mutect2, varscan2
- ZNF282 | c.1935C>G p.L645= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100021714, COSV50479994; called by muse, mutect2, varscan2
- ZNF574 | c.1119C>T p.F373= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs113091672, COSV55903296; called by muse, mutect2, varscan2
- ZNF77 | c.1533G>C p.V511= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as rs556368046, COSV100094649, COSV58821859; called by muse, mutect2, varscan2
- ZW10 | c.1971C>G p.L657= | Silent (SNP) | VAF 46/154 reads (30%) | catalogued as rs1173289148, COSV52316498; called by muse, mutect2, varscan2
- AP1G1 | c.1088+396G>A | Intron (SNP) | VAF 13/41 reads (32%) | catalogued as rs1250244674, COSV100250445; called by muse, mutect2, varscan2
- ATP6V1G2 | chr6:31548261 C>T | 5'Flank (SNP) | VAF 24/47 reads (51%) | catalogued as COSV58214384; called by muse, mutect2, varscan2
- HMGB1P1 | n.389G>C | RNA (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- MDS2 | n.157G>A | RNA (SNP) | VAF 11/25 reads (44%) | catalogued as rs772152398; called by muse, mutect2, varscan2
- MIR200A | n.41C>T | RNA (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- NIPSNAP3B | c.*1T>C | 3'UTR (SNP) | VAF 18/50 reads (36%) | catalogued as COSV101044477; called by muse, mutect2, varscan2
- P3H1 | c.2055+24G>C | Intron (SNP) | VAF 37/90 reads (41%) | catalogued as COSV52533717; called by muse, mutect2, varscan2
- PLCB1 | c.3423+11834G>A | Intron (SNP) | VAF 34/112 reads (30%) | catalogued as rs768356849, COSV62049946; called by muse, mutect2, varscan2
- PRMT2 | c.654+2181C>T | Intron (SNP) | VAF 26/99 reads (26%) | catalogued as COSV52455337; called by muse, varscan2
- SSPOP | n.6187C>G | RNA (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 14/43 reads (33%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TMC5 | c.1049-3494T>C | Intron (SNP) | VAF 26/113 reads (23%) | catalogued as COSV54903924; called by muse, mutect2, varscan2
